Somatic mutation profile of tumor specimen TARGET-10-PARCMG-03A (aliquot TARGET-10-PARCMG-03A-01D) from TARGET case TARGET-10-PARCMG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,476 days).
Specimen TARGET-10-PARCMG-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35fa04e4-51e7-4fd8-9423-e670ab35851f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCMG-10A (Blood Derived Normal), aliquot TARGET-10-PARCMG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2eed6995-11d7-4e5d-9ba3-f4050877ac38

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by mutect2, varscan2
- GALNT5 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763670213, COSV99374706; called by muse, varscan2
- TMEM268 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as rs781589029, COSV55986611; called by muse, mutect2, varscan2
- LRRC8C | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); called by mutect2, varscan2
- LMOD2 | c.351T>C p.Y117= | Silent (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
